Somatic mutation profile of tumor specimen TCGA-74-6584-01A (aliquot TCGA-74-6584-01A-11D-1845-08) from TCGA case TCGA-74-6584, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.4 years (20,232 days).
Specimen TCGA-74-6584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e34f498-b0ff-4252-9b70-9e5da1b72cc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6584-10A (Blood Derived Normal), aliquot TCGA-74-6584-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcba526f-1416-4f49-8a3e-bd04af0c49f9

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Splice Region 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGMO | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61123799, COSV61125083; called by muse, mutect2, varscan2
- ATOH1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV60038728; called by muse, mutect2, varscan2
- BOLL | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56573187; called by muse, mutect2, varscan2
- CEACAM7 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs782307166, COSV50072489; called by muse, mutect2, varscan2
- CEP350 | c.7285T>A p.F2429I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV62609434; called by muse, mutect2, varscan2
- COBL | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV54338582, COSV54357682; called by muse, varscan2
- COL4A2 | c.684+1G>A p.X228_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64633870; called by muse, mutect2, varscan2
- CRACDL | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV67410082; called by muse, mutect2, varscan2
- DSP | c.5264A>T p.Q1755L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs1389684020, COSV65795756; called by muse, mutect2, varscan2
- FBN2 | c.6617A>G p.Y2206C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); catalogued as COSV52544170; called by muse, mutect2, varscan2
- FOXN1 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs376900275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRNR | c.8317G>A p.G2773S | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs745519134, COSV64257975; called by muse, mutect2, varscan2
- IL31RA | c.1353C>T p.G451= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs755336880, COSV51683619; called by muse, varscan2
- LAMP2 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV52355137; called by muse, mutect2, varscan2
- OR10AG1 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV56633872; called by muse, mutect2, varscan2
- OR5AC2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs1460314675, COSV62280151; called by muse, mutect2, varscan2
- PHF2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63683762; called by muse, mutect2, varscan2
- PKHD1 | c.6215C>A p.P2072H | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61867699, COSV61893961; called by muse, mutect2
- PKHD1 | c.239T>C p.F80S | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61893971; called by muse, mutect2, varscan2
- PLXNC1 | c.3416A>T p.N1139I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51583594; called by muse, mutect2, varscan2
- PTGR2 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV50866934; called by muse, mutect2
- PWWP3B | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV61798620; called by muse, mutect2, varscan2
- RORC | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59095496; called by muse, mutect2
- SENP7 | c.2890A>G p.K964E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV58618977; called by muse, mutect2
- SSX5 | c.269G>A p.R90H (on ENST00000347757 / NM_175723.1; = p.R131H on NM_021015.4) | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs782483765, COSV61255908; called by muse, mutect2, varscan2
- THOC1 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs1414311034, COSV55277422; called by muse, mutect2, varscan2
- TINAGL1 | c.572A>C p.H191P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV54699964; called by muse, mutect2, varscan2
- VWA3A | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV55394819; called by muse, mutect2, varscan2
- AFF2 | c.1887dup p.Q630Tfs*6 | Frame Shift Ins (INS) | VAF 52/169 reads (31%) | called by mutect2, pindel, varscan2
- HRNR | c.6787T>A p.F2263I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by mutect2, varscan2
- HRNR | c.5377T>A p.F1793I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by mutect2, varscan2
- SUFU | c.722del p.G241Efs*26 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | called by mutect2, pindel, varscan2
- AADAC | c.930A>G p.K310= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV51761267; called by muse, mutect2, varscan2
- CCDC27 | c.1869C>T p.S623= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs760149058, COSV53903268; called by muse, mutect2, varscan2
- CFAP43 | c.3798T>C p.S1266= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs756517064, COSV63854958; called by muse, mutect2, varscan2
- COL10A1 | c.400C>T p.L134= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs1410639324, COSV54574616; called by muse, mutect2, varscan2
- DCAF8L1 | c.183C>T p.N61= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs778836758, COSV71595324, COSV71595359; called by muse, mutect2, varscan2
- DDI1 | c.1068G>A p.T356= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs760519987, COSV56391820; called by muse, mutect2, varscan2
- FASTKD5 | c.1518T>G p.T506= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV53909481, COSV99417879; called by muse, mutect2, varscan2
- MFAP1 | c.594C>A p.R198= | Silent (SNP) | VAF 7/176 reads (4%) | catalogued as COSV51041075; called by muse, mutect2
- ZNF184 | c.2229A>G p.K743= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV53005637; called by muse, mutect2
- ZNF827 | c.1893C>T p.D631= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs186229674, COSV65226152; called by muse, mutect2, varscan2
